Gene-level copy-number profile of tumor specimen TCGA-85-6175-01A from TCGA case TCGA-85-6175, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.6 years (23,228 days).
Specimen TCGA-85-6175-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.50874d9b-d527-46bc-a3df-7fa95f6707a0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-6175-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/760335b2-d31d-48dc-8376-099031fddbda

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,048; copy number 2: 43,738; copy number 3: 10,248; copy number 4: 2,278; copy number 5: 39; copy number 6: 4; copy number 7: 29; copy number 8: 48; copy number 9: 28; copy number 10: 102; copy number 13: 64; copy number 16: 22; copy number 17: 11; copy number 18: 32; copy number 19: 10; copy number 20: 79; copy number 22: 5; copy number 24: 5; copy number 39: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-6175-01A-11D-1816-01): tumor purity 0.3, ploidy 2.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 505 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,824,235–134,052,184, 3 genes, copy number 5 (within-gene range 2–5): RAB6B, C3orf36, SLCO2A1.
- chr3:150,202,174–152,841,439, 53 genes, copy number 5–7: AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, AC011317.1, SIAH2, SIAH2-AS1, CLRN1-AS1, MINDY4B, AC020636.2, AC020636.1, CLRN1, AC108726.1, MED12L, RNA5SP145, GPR171, P2RY14, SETP11, AC078816.1, GPR87, P2RY13, P2RY12, IGSF10, MRPL42P6, AC117454.1, MIR5186, LINC02066, AADACL2, AADACL2-AS1, AC068647.1, AADACP1, AC068647.2, AADAC, SUCNR1, AC108718.1, MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA, AC026347.1, AC092924.1, AC092924.2, ATP5MGP5, P2RY1.
- chr6:65,302,522–71,058,476, 44 genes, copy number 7–22: AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1.
- chr7:70,837,738–71,713,600, 4 genes, copy number 6 (within-gene range 4–6): AC073873.1, GALNT17, MIR3914-1, MIR3914-2.
- chr9:12,698,554–19,786,928, 90 genes, copy number 10–39 (within-gene range 1–39) (broad region; genes not listed).
- chr12:10,604,193–12,357,067, 59 genes, copy number 8–17: MAGOHB, STYK1, YBX3, LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6, BCL2L14, PTMAP9, MIR1244-4, LRP6, AC007537.1, RNU6-545P, AC007621.3, RNU6-318P, MANSC1, RPL23AP66, LOH12CR2.
- chr12:42,456,757–43,163,110, 14 genes, copy number 13: PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461.
- chr12:57,546,026–60,096,071, 58 genes, copy number 5–19: KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1.
- chr12:62,850,738–70,637,440, 179 genes, copy number 5–24 (broad region; genes not listed).
- chr12:70,671,918–70,672,856, 1 gene, copy number 20: FAHD2P1.

Autosomal genes at a single copy (total copy number 1): 2,312. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
